Somatic mutation profile of tumor specimen TARGET-20-PARSAN-04A (aliquot TARGET-20-PARSAN-04A-01D) from TARGET case TARGET-20-PARSAN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,420 days).
Specimen TARGET-20-PARSAN-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a60f459d-f0c6-4ddf-9f10-7532c6120561.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARSAN-14A (Bone Marrow Normal), aliquot TARGET-20-PARSAN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/971887dc-1740-4e74-b1c0-f9661e45f862

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 4, Silent 3, 5'UTR 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF3 | c.2162G>A p.S721N | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52462785; called by muse, mutect2, varscan2
- ARID2 | c.3964A>T p.I1322F | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs149367629; called by muse, mutect2, varscan2
- CACNA1F | c.5882G>T p.R1961L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.097); catalogued as rs782337448, COSV54294494; called by muse, mutect2, varscan2
- GAREM1 | c.2165G>A p.C722Y (on ENST00000269209 / NM_001242409.2; = p.C721Y on NM_022751.3) | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs181354924; called by muse, mutect2
- PCLO | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs796149623, COSV61659860; called by muse, mutect2
- WT1 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV60066682, COSV60086086; called by muse, mutect2, varscan2
- WT1 | c.1105_1108dup p.A370Vfs*4 | Frame Shift Ins (INS) | VAF 32/170 reads (19%) | catalogued as COSV60065440; called by mutect2, varscan2
- ADCY5 | c.1690G>C p.G564R | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCLO | c.3719dup p.P1241Afs*4 | Frame Shift Ins (INS) | VAF 108/531 reads (20%) | called by mutect2, varscan2
- KMT2A | c.1938A>G p.P646= | Silent (SNP) | VAF 115/459 reads (25%) | catalogued as rs782137297; ClinVar: likely benign; called by muse, mutect2, varscan2
- MLLT1 | c.234C>T p.Y78= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as rs199516291; called by muse, mutect2, varscan2
- PTPRF | c.3504A>G p.Q1168= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs765214291; called by muse, mutect2
- CARD11 | c.-321G>C | 5'UTR (SNP) | VAF 6/25 reads (24%) | catalogued as rs1419554442; called by muse, mutect2
- KCNH4 | c.*42G>A | 3'UTR (SNP) | VAF 18/83 reads (22%) | catalogued as rs760725342, COSV52920813; called by muse, mutect2, varscan2
- LIN28B | c.*4115A>C | 3'UTR (SNP) | VAF 90/408 reads (22%) | catalogued as rs1429629186; called by muse, mutect2, varscan2
- PTK6 | c.-60G>A | 5'UTR (SNP) | VAF 6/25 reads (24%) | catalogued as rs544773789; called by muse, mutect2, varscan2
- SIAE | c.*3122T>C | 3'UTR (SNP) | VAF 110/420 reads (26%) | catalogued as rs1463032371; called by muse, mutect2, varscan2
- SMARCA5 | c.*231C>T | 3'UTR (SNP) | VAF 63/300 reads (21%) | catalogued as rs1056030853; called by muse, mutect2, varscan2
